National Lung Screening Trial (NLST) participant 104575 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 65 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 179): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 140 kVp, 50 mA, display field of view 33 cm, reconstruction filter GE Standard.
- T1: No screening result: Not Compliant - Refused a screen.
- T2: No screening result: Not Expected - Cancer in screening window.

Abnormalities recorded by the reading radiologist on the CT screens (3 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Emphysema.
- T0 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 7 mm, longest perpendicular diameter 6 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 31.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a missed screen; study year of the first confirmed lung cancer: T1; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 726, study year T1. Site: lung, NOS (ICD-O-3 C34.9), determined from cytology. Primary tumour location: unknown location. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: cannot be assessed (GX). AJCC 6th edition staging: stage IIIB (best stage, from the stage-only field); clinical T4 N3 MX. AJCC 7th edition staging: stage IV; clinical T3 N3 M1a. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 393.
